Somatic mutation profile of tumor specimen TCGA-75-5146-01A (aliquot TCGA-75-5146-01A-01D-1625-08) from TCGA case TCGA-75-5146, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-75-5146-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62a24d2d-9e15-4884-b569-76bbbe81439c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-75-5146-10A (Blood Derived Normal), aliquot TCGA-75-5146-10A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95db3ed6-4817-46bf-bad4-5f7ae09c5374

The open-access MAF lists 200 somatic variants for this specimen: 145 protein-altering or splice-affecting, 50 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 125, Silent 50, Nonsense Mutation 10, Frame Shift Del 5, RNA 3, Splice Site 3, Frame Shift Ins 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>T p.G509V (on ENST00000288602 / NM_001374244.1; = p.G469V on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- STK11 | c.717G>T p.W239C | Missense Mutation (SNP) | VAF 11/22 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM022255, CM1510368, COSV58820077, COSV58827670; called by muse, mutect2, varscan2
- ABCB1 | c.2397+1G>T p.X799_splice | Splice Site (SNP) | VAF 9/32 reads (28%) | catalogued as COSV55945099; called by mutect2, varscan2
- ADAMTS17 | c.2042G>T p.G681V | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51473134; called by muse, mutect2, varscan2
- ADAMTS2 | c.736C>A p.L246I | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV51072073; called by muse, mutect2, varscan2
- ADARB1 | c.1291C>T p.R431* | Nonsense Mutation (SNP) | VAF 4/37 reads (11%) | catalogued as COSV62344243; called by muse, mutect2, varscan2
- ADGRB3 | c.1725G>T p.L575F | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV65382738; called by muse, mutect2, varscan2
- ADGRL3 | c.3959A>G p.N1320S (on ENST00000506720 / NM_001322402.2; = p.N1209S on NM_015236.6) | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as COSV72229277; called by muse, mutect2, varscan2
- ANGPT4 | c.1432G>T p.G478C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67920596; called by muse, mutect2, varscan2
- ANKRD44 | c.1015G>T p.G339C | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56549388; called by muse, mutect2, varscan2
- APOB | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1168873517, COSV51923138; called by muse, mutect2, varscan2
- ARAP2 | c.637G>T p.D213Y | Missense Mutation (SNP) | VAF 89/197 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.086); catalogued as COSV58282526; called by muse, mutect2, varscan2
- ARHGEF17 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as COSV55229369; called by muse, mutect2, varscan2
- ASCC3 | c.4540C>T p.R1514* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as rs1164835174, COSV64972219; called by muse, mutect2, varscan2
- ASPM | c.7540T>A p.Y2514N | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54124616; called by muse, mutect2, varscan2
- ATP7A | c.3928G>T p.A1310S | Missense Mutation (SNP) | VAF 72/121 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58442433, COSV58447409; called by muse, mutect2, varscan2
- ATRNL1 | c.2246G>A p.G749E | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV61797087; called by muse, mutect2, varscan2
- BTAF1 | c.2408T>C p.I803T | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV56429889; called by muse, mutect2
- CHRNB3 | c.1358G>T p.W453L | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV51493163; called by muse, mutect2, varscan2
- CKAP2 | c.1198G>A p.E400K (on ENST00000378037 / NM_001098525.2; = p.E399K on NM_018204.5) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV51620800; called by muse, mutect2, varscan2
- CLASP1 | c.2512del p.R838Afs*20 | Frame Shift Del (DEL) | VAF 17/96 reads (18%) | catalogued as COSV55313632, COSV55323446; called by mutect2, pindel, varscan2
- COL11A2 | c.266T>A p.V89D | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV59493529; called by muse, mutect2, varscan2
- COMMD3 | c.415A>G p.N139D | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV64958687; called by muse, mutect2, varscan2
- CRB1 | c.1576del p.R526Efs*8 | Frame Shift Del (DEL) | VAF 30/107 reads (28%) | catalogued as COSV66334393; called by mutect2, pindel, varscan2
- CUBN | c.10433T>A p.V3478D | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV64707804; called by muse, mutect2
- DBT | c.1087C>T p.Q363* | Nonsense Mutation (SNP) | VAF 90/311 reads (29%) | catalogued as COSV64494933; called by muse, mutect2, varscan2
- DEPDC1 | c.704T>C p.I235T | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs759407253, COSV63957537; called by muse, mutect2, varscan2
- DGKA | c.1859G>A p.G620E | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.315); catalogued as rs923673423, COSV59384168; called by muse, mutect2, varscan2
- DIDO1 | c.5969G>A p.G1990D | Missense Mutation (SNP) | VAF 77/243 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); catalogued as COSV56613638; called by muse, mutect2, varscan2
- DNAH7 | c.5461G>T p.D1821Y | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV56751780; called by muse, mutect2, varscan2
- DOCK10 | c.962G>T p.C321F | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.027); catalogued as COSV51347972; called by muse, mutect2, varscan2
- DPYSL3 | c.1084A>C p.M362L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.641); catalogued as COSV58323959; called by muse, mutect2, varscan2
- EMILIN3 | c.2285C>A p.P762Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV60035081; called by muse, mutect2, varscan2
- ERAL1 | c.34G>A p.V12I | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as COSV54739171; called by muse, mutect2, varscan2
- ERICH1 | c.508C>G p.Q170E | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs769065556, COSV50641548; called by muse, mutect2, varscan2
- ERICH3 | c.4342C>A p.Q1448K | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV58599160; called by muse, mutect2, varscan2
- FAT1 | c.3487G>T p.A1163S | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101499624, COSV71671920; called by muse, mutect2, varscan2
- FAT3 | c.11427G>T p.Q3809H | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV53075480; called by muse, mutect2, varscan2
- FBLIM1 | c.839G>T p.S280I | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60028576; called by muse, mutect2, varscan2
- FBXO2 | c.611A>T p.K204M | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV52353652; called by muse, mutect2, varscan2
- FGF19 | c.527C>A p.P176H | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV53735725, COSV53736447; called by muse, mutect2, varscan2
- FRMPD2 | c.1328C>A p.T443K | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751468516, COSV59715096; called by muse, mutect2, varscan2
- FSIP2 | c.17978C>A p.T5993K | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as COSV58100572; called by muse, mutect2, varscan2
- FSTL5 | c.1396C>A p.Q466K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV60181466; called by muse, mutect2, varscan2
- FUT8 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV61292681; called by muse, mutect2, varscan2
- GABRA5 | c.701C>A p.T234N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as COSV59475780; called by muse, mutect2, varscan2
- GAPVD1 | c.2291G>T p.G764V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52920103; called by muse, mutect2, varscan2
- GLI1 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760141461, COSV57357897; called by muse, mutect2, varscan2
- GLI1 | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as COSV57357909; called by muse, mutect2, varscan2
- GRIK2 | c.970T>A p.Y324N | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59712278; called by muse, mutect2, varscan2
- GSTA5 | c.322C>G p.L108V | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV52861294; called by muse, mutect2, varscan2
- HDAC6 | c.265G>T p.V89L | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV61927465; called by muse, mutect2, varscan2
- HMGCLL1 | c.747C>A p.D249E | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51440522; called by muse, mutect2, varscan2
- INSIG2 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs1558833828, COSV55521815; called by muse, mutect2, varscan2
- ITK | c.559C>A p.P187T | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.216); catalogued as COSV70060380, COSV70064906; called by muse, mutect2, varscan2
- JAK2 | c.539G>C p.G180A | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.784); catalogued as COSV67576263, COSV67600023; called by muse, mutect2, varscan2
- KCNB2 | c.929G>C p.R310T | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73048892; called by muse, mutect2, varscan2
- KCNH7 | c.2242G>T p.G748W | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59784904; called by muse, mutect2, varscan2
- KCNMA1 | c.3499G>T p.V1167L (on ENST00000286628 / NM_001161352.2; = p.V1109L on NM_002247.4) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54227414; called by muse, mutect2, varscan2
- KCNQ1 | c.527G>C p.W176S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50100282; called by muse, mutect2, varscan2
- KLHL4 | c.680G>C p.G227A | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV64139046; called by muse, mutect2, varscan2
- KRT34 | c.144C>A p.C48* | Nonsense Mutation (SNP) | VAF 19/105 reads (18%) | catalogued as COSV67449237; called by muse, mutect2, varscan2
- KRT6B | c.1315C>A p.Q439K | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV52881853; called by muse, mutect2, varscan2
- KRTAP10-9 | c.784T>A p.C262S | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV59951696; called by muse, mutect2, varscan2
- LMNTD1 | c.162G>T p.Q54H | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.62); catalogued as COSV51444706; called by muse, mutect2, varscan2
- LRRC23 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as COSV50386679, COSV50397838; called by muse, mutect2, varscan2
- MLIP | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as COSV51425831, COSV99229056; called by muse, mutect2
- MYH1 | c.5134G>A p.D1712N | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV56843669; called by muse, mutect2, varscan2
- MYH3 | c.1960-1G>T p.X654_splice | Splice Site (SNP) | VAF 32/105 reads (30%) | catalogued as rs1167577576, COSV56860871; called by muse, mutect2, varscan2
- MYLK | c.2768T>C p.M923T | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV60604706; called by muse, mutect2, varscan2
- NLGN1 | c.1253T>G p.F418C | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100849376, COSV64323677; called by muse, mutect2, varscan2
- NMUR2 | c.1036C>A p.H346N | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV54917058; called by muse, mutect2, varscan2
- NPAP1 | c.1397C>A p.P466H | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.32); catalogued as COSV61504435; called by muse, mutect2, varscan2
- NPAP1 | c.2257G>T p.V753F | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.766); catalogued as COSV61504449; called by muse, mutect2, varscan2
- NRSN2 | c.269T>C p.L90P | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV66526543; called by muse, mutect2, varscan2
- NUDT17 | c.742C>A p.L248I | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV57906643; called by muse, mutect2, varscan2
- OPN5 | c.826G>C p.A276P | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV55244200; called by muse, mutect2, varscan2
- OR3A1 | c.566A>G p.Q189R | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV60162512; called by muse, mutect2, varscan2
- OR52E4 | c.499C>G p.R167G | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV57623791, COSV57625916; called by muse, mutect2, varscan2
- OR5AR1 | c.118G>T p.V40L | Missense Mutation (SNP) | VAF 61/246 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV57252753; called by muse, mutect2, varscan2
- OR8U1 | c.546G>T p.M182I | Missense Mutation (SNP) | VAF 42/308 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100164006; called by mutect2, varscan2
- OSR2 | c.464C>A p.P155Q | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as rs373472912, COSV52555478; called by muse, mutect2, varscan2
- OVCH1 | c.626A>T p.K209M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV58959528; called by muse, mutect2
- PAPPA2 | c.2797C>A p.P933T | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62790680; called by muse, mutect2, varscan2
- PCDHGB3 | c.1748A>T p.E583V | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV53898287; called by muse, mutect2, varscan2
- PDZD8 | c.2411A>T p.H804L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV53688436; called by muse, mutect2, varscan2
- PIGR | c.2008G>A p.D670N | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1283428252, COSV62903228; called by muse, mutect2, varscan2
- PIK3AP1 | c.1328T>A p.L443H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV59530316; called by muse, mutect2, varscan2
- PIK3R5 | c.2227C>T p.R743C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs761616260, COSV52650485; called by muse, mutect2
- PIK3R5 | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.309); catalogued as COSV52650492; called by muse, mutect2, varscan2
- PLD5 | c.1522C>A p.P508T (on ENST00000442594; = p.P446T on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/246 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV59133531; called by muse, mutect2, varscan2
- PLEKHG4B | c.3547C>A p.P1183T (on ENST00000283426; = p.P1539T on NM_052909.5) | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.581); catalogued as COSV52043430; called by muse, mutect2, varscan2
- PNISR | c.806A>G p.K269R | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV65078630; called by muse, mutect2, varscan2
- PNPLA5 | c.1094G>T p.W365L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99336697; called by muse, mutect2, varscan2
- POLI | c.1120T>C p.Y374H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.16); catalogued as COSV54187680; called by muse, mutect2, varscan2
- PXDN | c.803G>C p.R268T | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV53226887, COSV53231844; called by muse, mutect2
- PXDNL | c.4098C>A p.S1366R | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV62477992; called by muse, mutect2, varscan2
- RP1 | c.6114C>A p.H2038Q | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV55110020; called by muse, mutect2, varscan2
- RPLP0 | c.539T>G p.I180S | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV56103732; called by muse, mutect2, varscan2
- SALL1 | c.121G>C p.D41H | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV51753195, COSV51757471; called by muse, mutect2, varscan2
- SDK2 | c.3427G>T p.G1143W | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV66181249; called by muse, mutect2, varscan2
- SEC14L4 | c.1184A>C p.Q395P | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV55398350; called by muse, mutect2, varscan2
- SEC61A2 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV53650587; called by muse, mutect2, varscan2
- SH3BP2 | c.1410G>T p.L470F | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV62553530; called by muse, mutect2, varscan2
- SLCO4C1 | c.1463A>C p.Y488S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV60512747; called by muse, mutect2, varscan2
- SLIT2 | c.914T>C p.I305T | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV56560089; called by muse, mutect2, varscan2
- SLITRK1 | c.829C>A p.Q277K | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.028); catalogued as COSV65674231; called by muse, mutect2, varscan2
- SNX25 | c.1882C>G p.L628V | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV53011511; called by muse, mutect2, varscan2
- SPATA31A1 | c.3663G>A p.M1221I | Missense Mutation (SNP) | VAF 55/237 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1191558265; called by muse, mutect2, varscan2
- SPRY3 | c.415C>A p.H139N | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV57141818; called by muse, mutect2, varscan2
- STK32C | c.844G>T p.G282W | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53837486; called by muse, mutect2
- SYCP1 | c.682C>G p.L228V | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65694533; called by muse, mutect2, varscan2
- TAAR6 | c.977T>C p.V326A | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as COSV51582626; called by muse, mutect2, varscan2
- TBC1D1 | c.2126del p.P709Hfs*44 | Frame Shift Del (DEL) | VAF 56/169 reads (33%) | catalogued as COSV104373445; called by mutect2, pindel, varscan2
- TBC1D14 | c.1348G>T p.E450* | Nonsense Mutation (SNP) | VAF 23/79 reads (29%) | catalogued as COSV68984466, COSV68987410; called by muse, mutect2, varscan2
- TBX5 | c.1006C>T p.H336Y | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as COSV59866264; called by muse, mutect2
- THBS2 | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 40/136 reads (29%) | catalogued as COSV64677037, COSV64681219; called by muse, mutect2, varscan2
- THEMIS | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.453); catalogued as COSV64069243; called by muse, mutect2, varscan2
- TIMD4 | c.280G>T p.D94Y | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV50853965, COSV50855746; called by muse, mutect2, varscan2
- TRIM29 | c.353C>A p.P118H | Missense Mutation (SNP) | VAF 77/318 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); catalogued as COSV59279040; called by muse, mutect2, varscan2
- TRIM39 | c.778A>C p.K260Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.223); catalogued as COSV64954900; called by muse, mutect2, varscan2
- TRPT1 | c.157+2T>G p.X53_splice (on ENST00000317459 / NM_001160393.1; = p.X4_splice on NM_031472.4) | Splice Site (SNP) | VAF 8/22 reads (36%) | catalogued as COSV54172036; called by muse, mutect2, varscan2
- TTLL7 | c.757G>T p.V253L | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV53081370, COSV53085301; called by muse, mutect2, varscan2
- TXNL4B | c.69G>T p.E23D | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51696220; called by muse, mutect2, varscan2
- UGGT1 | c.2164A>G p.R722G | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.196); catalogued as COSV52132350; called by muse, mutect2, varscan2
- USH2A | c.1889C>A p.A630E | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.714); catalogued as COSV56327476; called by muse, mutect2, varscan2
- UTS2B | c.276G>T p.K92N | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV61277341; called by muse, mutect2, varscan2
- VAX1 | c.104C>A p.A35E | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV53327482, COSV53329789; called by muse, mutect2, varscan2
- XKR7 | c.1466C>A p.A489E | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated (0.47); PolyPhen benign (0.084); catalogued as COSV73812883, COSV73813199; called by muse, mutect2, varscan2
- ZBTB45 | c.487G>T p.G163W | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as COSV63523009; called by muse, mutect2, varscan2
- ZIC2 | c.553G>T p.G185C | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66254675; called by muse, mutect2, varscan2
- ZNF202 | c.421G>T p.G141C | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV60246380; called by muse, mutect2, varscan2
- ZNF223 | c.67G>T p.G23W | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV71571773; called by muse, mutect2, varscan2
- ZNF280A | c.277G>T p.V93L | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.014); catalogued as COSV57479342; called by muse, mutect2, varscan2
- ZNF285 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1346971028, COSV58407935, COSV58408858; called by muse, mutect2, varscan2
- ZNF397 | c.538T>C p.C180R | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.243); catalogued as COSV54349854; called by muse, mutect2, varscan2
- ZNF536 | c.1563C>A p.Y521* | Nonsense Mutation (SNP) | VAF 22/107 reads (21%) | catalogued as COSV62818454; called by muse, mutect2, varscan2
- ZNF665 | c.1195G>C p.G399R (on ENST00000600412; = p.G464R on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67213190, COSV67213535; called by muse, mutect2, varscan2
- ZNF670 | c.325G>T p.G109* | Nonsense Mutation (SNP) | VAF 35/175 reads (20%) | catalogued as COSV63607583; called by muse, mutect2, varscan2
- ZNF71 | c.178_179insA p.G60Efs*18 | Frame Shift Ins (INS) | VAF 6/34 reads (18%) | catalogued as COSV60146436; called by mutect2, pindel, varscan2
- FAM177B | c.404del p.K135Sfs*18 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | called by mutect2, pindel, varscan2
- LRIG1 | c.569dup p.L191Afs*121 | Frame Shift Ins (INS) | VAF 32/78 reads (41%) | called by mutect2, pindel, varscan2
- MUC2 | c.1564G>C p.A522P | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MYT1L | c.3059del p.F1020Sfs*17 | Frame Shift Del (DEL) | VAF 20/33 reads (61%) | called by mutect2, varscan2
- PRKY | c.385G>T p.V129L | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- ACACA | c.3663G>T p.L1221= | Silent (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- AKAP3 | c.1479C>G p.S493= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV57413746; called by muse, mutect2, varscan2
- CACNA1E | c.3234C>T p.D1078= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV62382174; called by muse, mutect2, varscan2
- CRISP3 | c.222G>T p.V74= (on ENST00000371159 / NM_001368123.1; = p.V56= on NM_006061.4) | Silent (SNP) | VAF 59/216 reads (27%) | catalogued as COSV53818966, COSV53823097; called by muse, mutect2, varscan2
- CYP4F8 | c.721C>A p.R241= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs756196035, COSV100358002, COSV57853075; called by muse, mutect2, varscan2
- ERICH3 | c.1005C>G p.T335= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV58598872, COSV58599165; called by muse, mutect2, varscan2
- FRRS1 | c.1092C>T p.S364= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV54920323; called by muse, mutect2, varscan2
- FSHR | c.1128C>A p.A376= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV58617547; called by muse, mutect2, varscan2
- GALNT17 | c.966C>A p.T322= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs770747325, COSV61147820; called by muse, mutect2
- GAS7 | c.564G>T p.P188= (on ENST00000432992 / NM_201433.2; = p.P48= on NM_003644.3) | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV60431411, COSV60438018; called by muse, mutect2, varscan2
- HOXA2 | c.990A>G p.T330= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV56065228; called by muse, mutect2, varscan2
- IGHG3 | c.894G>T p.L298= | Silent (SNP) | VAF 65/176 reads (37%) | called by muse, mutect2, varscan2
- IGKV1-16 | c.126C>T p.T42= | Silent (SNP) | VAF 92/253 reads (36%) | catalogued as rs373147392; called by muse, varscan2
- IL21R | c.138G>T p.T46= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV61971691, COSV61973193; called by muse, mutect2, varscan2
- KRT4 | c.1191C>A p.A397= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV53405654; called by muse, mutect2, varscan2
- LHX5 | c.228G>T p.L76= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as COSV55661912; called by muse, mutect2, varscan2
- LRGUK | c.451C>T p.L151= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV53634094; called by muse, mutect2, varscan2
- LRMDA | c.594C>T p.L198= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV65285620; called by muse, mutect2, varscan2
- MAP1B | c.2400C>A p.G800= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV57093777; called by muse, mutect2, varscan2
- MTNR1B | c.594C>A p.T198= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV57065327; called by muse, mutect2, varscan2
- MUC5B | c.5925C>A p.P1975= | Silent (SNP) | VAF 44/131 reads (34%) | catalogued as COSV71589960; called by muse, mutect2, varscan2
- MYLK2 | c.414A>T p.A138= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV65658493; called by muse, mutect2, varscan2
- OR1M1 | c.246G>T p.L82= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV70036419; called by muse, mutect2, varscan2
- OR2AG1 | c.138C>A p.L46= | Silent (SNP) | VAF 34/145 reads (23%) | catalogued as COSV56625325; called by muse, mutect2, varscan2
- OR2T1 | c.111A>G p.A37= | Silent (SNP) | VAF 29/147 reads (20%) | catalogued as COSV63541143; called by muse, mutect2, varscan2
- P2RY6 | c.711G>T p.A237= | Silent (SNP) | VAF 35/136 reads (26%) | catalogued as COSV62935658; called by muse, mutect2, varscan2
- PANX3 | c.507C>T p.S169= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as rs147550190; called by muse, mutect2, varscan2
- PCDHGA7 | c.1764G>C p.V588= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV53898295; called by muse, mutect2, varscan2
- PFDN2 | c.48G>T p.A16= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV63501140; called by muse, mutect2, varscan2
- PGC | c.282C>T p.S94= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV63122161; called by muse, mutect2, varscan2
- PIGN | c.126A>T p.P42= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV62947776; called by muse, mutect2, varscan2
- PIK3R6 | c.1221G>T p.L407= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV61006668; called by muse, mutect2, varscan2
- POTEH | c.219G>A p.R73= | Silent (SNP) | VAF 75/500 reads (15%) | catalogued as rs1385558672, COSV100625243, COSV58879753; called by muse, varscan2
- PPP1R3D | c.450C>T p.F150= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV62563836; called by muse, mutect2, varscan2
- PRND | c.336C>T p.T112= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV59896135; called by muse, mutect2, varscan2
- PURG | c.403C>A p.R135= | Silent (SNP) | VAF 41/161 reads (25%) | catalogued as COSV53296010; called by muse, mutect2, varscan2
- R3HDML | c.90C>G p.T30= | Silent (SNP) | VAF 29/53 reads (55%) | catalogued as COSV53835170; called by muse, mutect2, varscan2
- SI | c.975C>A p.I325= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV52265984, COSV52279634; called by muse, mutect2, varscan2
- SLC15A1 | c.1623T>A p.P541= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as COSV64729935; called by muse, mutect2, varscan2
- SNAP25 | c.384C>A p.A128= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV54770398; called by muse, mutect2, varscan2
- SRGAP1 | c.1773C>T p.L591= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs984384990, COSV61894393; called by muse, mutect2, varscan2
- STIM1 | c.1347A>T p.S449= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV56151548; called by muse, mutect2, varscan2
- TENM3 | c.6111G>T p.T2037= | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as rs753521401, COSV69299336, COSV69312045; called by muse, mutect2, varscan2
- TRIML1 | c.657C>G p.T219= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV60193294, COSV60194097, COSV60194643; called by muse, mutect2, varscan2
- TRPC4 | c.1587A>G p.A529= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as COSV58990495; called by muse, mutect2, varscan2
- UBIAD1 | c.624G>T p.G208= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV65147508; called by muse, mutect2, varscan2
- UNC45B | c.1662C>G p.A554= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV52092242; called by muse, mutect2
- WBP1 | c.183G>C p.L61= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV51968105; called by muse, mutect2, varscan2
- XAGE5 | c.219A>G p.S73= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV63567593; called by muse, mutect2, varscan2
- ZDHHC13 | c.936C>T p.F312= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV67980318; called by muse, mutect2, varscan2
- BIRC8 | n.1452G>T | RNA (SNP) | VAF 36/167 reads (22%) | catalogued as rs867603245, COSV70346456; called by muse, mutect2, varscan2
- DST | c.4296+3906C>A | Intron (SNP) | VAF 46/193 reads (24%) | catalogued as rs767671723, COSV99757867; called by muse, mutect2, varscan2
- OPRM1 | c.1164+1811C>A | Intron (SNP) | VAF 41/185 reads (22%) | catalogued as COSV100001789; called by muse, mutect2, varscan2
- TMEM183B | n.107G>A | RNA (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- XIST | n.9506C>A | RNA (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
